Somatic mutation profile of tumor specimen TCGA-2G-AALG-01A (aliquot TCGA-2G-AALG-01A-11D-A42Y-10) from TCGA case TCGA-2G-AALG, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Tissue or organ of origin: Testis, NOS.
Specimen TCGA-2G-AALG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa545b1c-afe6-48e6-9750-9a63555dee19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AALG-10A (Blood Derived Normal), aliquot TCGA-2G-AALG-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1c135be-0b18-43bf-97a3-3163d411c884

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 2, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- XRN2 | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs1262828363, COSV65869359; called by muse, mutect2, varscan2
- CBX1 | c.125G>A p.W42* | Nonsense Mutation (SNP) | VAF 18/204 reads (9%) | called by muse, mutect2
- JAKMIP1 | c.235_237del p.E79del | In Frame Del (DEL) | VAF 10/51 reads (20%) | called by pindel, varscan2
- TRAF7 | c.412T>C p.F138L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- INKA1 | c.129G>A p.Q43= | Silent (SNP) | VAF 14/52 reads (27%) | called by muse, varscan2
- RGL1 | c.153G>A p.Q51= (on ENST00000360851 / NM_001297672.2; = p.Q86= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as rs1265841867; called by muse, mutect2, varscan2
- RNF103 | c.189C>G p.P63= | Silent (SNP) | VAF 23/282 reads (8%) | catalogued as rs139047742; called by muse, mutect2
